Somatic mutation profile of tumor specimen PCProject_0225_T2_WES (aliquot PCProject_0225_T2_WES_1) from CMI case PCProject_0225, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.0 years (20,808 days).
Specimen PCProject_0225_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8fc5bc3-f2a0-4397-b651-a76abae42e3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0225_SALIVA (DNA), aliquot PCProject_0225_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fda1974b-81f8-4670-a43c-a0506deffa20

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Intron 5, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 34/494 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ATP7B | c.3797G>A p.G1266E | Missense Mutation (SNP) | VAF 126/675 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1566444586, CM131494, CM970148, COSV54440724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B3 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185225335, COSV59540331; called by muse, mutect2, varscan2
- CCDC22 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs781929389, COSV66050894; called by muse, mutect2, varscan2
- GRID1 | c.1513A>T p.I505F | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60026370; called by muse, mutect2, varscan2
- MYO9A | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772538066, COSV61849412; called by muse, mutect2, varscan2
- OR5R1 | c.857A>C p.N286T | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56572059; called by muse, mutect2, varscan2
- ZNF831 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); catalogued as rs749815984; called by muse, mutect2, varscan2
- GPR149 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- KLHL10 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRP1B | c.11185T>C p.C3729R | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NXF3 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SDK1 | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTS2 | c.2595G>A p.P865= | Silent (SNP) | VAF 48/332 reads (14%) | catalogued as rs142355768; called by muse, mutect2, varscan2
- CFAP92 | c.1917G>A p.A639= | Silent (SNP) | VAF 30/194 reads (15%) | catalogued as rs974422389; called by muse, mutect2, varscan2
- CPNE3 | c.297A>G p.E99= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, varscan2
- FCGBP | c.10284G>T p.G3428= | Silent (SNP) | VAF 30/672 reads (4%) | called by muse, mutect2
- FSHR | c.18C>G p.V6= | Silent (SNP) | VAF 91/608 reads (15%) | catalogued as rs1294601487, COSV100437567; called by muse, mutect2, varscan2
- TRIM41 | c.1257G>A p.R419= | Silent (SNP) | VAF 47/324 reads (15%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-3868del | Intron (DEL) | VAF 66/459 reads (14%) | called by mutect2, pindel, varscan2
- ADAM22 | c.86-36C>A | Intron (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- CACNA1D | c.5040+33A>G | Intron (SNP) | VAF 29/685 reads (4%) | called by muse, mutect2
- GCLC | c.759+17A>G | Intron (SNP) | VAF 55/330 reads (17%) | called by muse, mutect2, varscan2
- RMDN1 | c.894+198C>T | Intron (SNP) | VAF 20/180 reads (11%) | catalogued as rs554074243; called by muse, mutect2, varscan2
- SUCO | chr1:172532702 A>T | 5'Flank (SNP) | VAF 118/799 reads (15%) | called by muse, mutect2, varscan2
